Somatic mutation profile of tumor specimen TCGA-YF-AA3M-01A (aliquot TCGA-YF-AA3M-01A-11D-A42E-08) from TCGA case TCGA-YF-AA3M, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 57.8 years (21,097 days).
Specimen TCGA-YF-AA3M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 47cca7b2-f109-4080-9c40-8db5aca6c678.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YF-AA3M-10D (Blood Derived Normal), aliquot TCGA-YF-AA3M-10D-01D-A42H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/93973a62-ab8b-4648-b78e-e0dfadc9c6b5

The open-access MAF lists 192 somatic variants for this specimen: 122 protein-altering or splice-affecting, 66 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 102, Silent 66, Nonsense Mutation 11, Frame Shift Del 6, 5'Flank 2, Nonstop Mutation 1, Frame Shift Ins 1, 3'UTR 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSRP3 | c.420G>C p.W140C | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1565050320, COSV99788216; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.839G>C p.R280T | Missense Mutation (SNP) | VAF 17/23 reads (74%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABHD16A | c.406C>T p.R136W | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as rs145269002; called by muse, varscan2
- ADCYAP1R1 | c.333G>A p.M111I | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV58441763; called by muse, mutect2, varscan2
- ANKRD12 | c.1703C>A p.S568* | Nonsense Mutation (SNP) | VAF 10/67 reads (15%) | catalogued as rs1471043619, COSV100041101, COSV50820042; called by muse, mutect2, varscan2
- ANKRD12 | c.3933C>G p.S1311R | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV50819885; called by muse, mutect2, varscan2
- ANKRD12 | c.4148C>T p.S1383L | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.162); catalogued as COSV50819914; called by muse, mutect2, varscan2
- ANKRD35 | c.790C>G p.P264A | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.145); catalogued as COSV62909665; called by muse, mutect2, varscan2
- ARMC1 | c.110A>G p.D37G | Missense Mutation (SNP) | VAF 51/121 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.396); catalogued as COSV52533156; called by muse, mutect2, varscan2
- ATP13A3 | c.1904T>C p.M635T | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as COSV55461932; called by muse, mutect2, varscan2
- ATR | c.5545G>C p.E1849Q | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV63384492, COSV63387168; called by muse, mutect2
- B4GALNT2 | c.857T>C p.I286T | Missense Mutation (SNP) | VAF 65/126 reads (52%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as rs1353708476, COSV55925052; called by muse, mutect2, varscan2
- BCHE | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 51/87 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); catalogued as COSV52254114; called by muse, mutect2, varscan2
- BCL2L11 | c.440G>A p.W147* (on ENST00000393256 / NM_138621.5; = p.W87* on NM_006538.5) | Nonsense Mutation (SNP) | VAF 19/28 reads (68%) | catalogued as rs1321821639, COSV58033768; called by muse, mutect2, varscan2
- BIRC6 | c.13757C>T p.S4586L | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101428139; called by muse, mutect2, varscan2
- BIRC6 | c.13834C>G p.L4612V | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as COSV70196146; called by muse, mutect2, varscan2
- BRWD1 | c.941C>T p.P314L | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1207825138, COSV60893229; called by muse, mutect2, varscan2
- C1GALT1 | c.892C>A p.P298T | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.053); catalogued as COSV56178868; called by muse, mutect2, varscan2
- C1GALT1 | c.893C>A p.P298H | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.865); catalogued as rs1296984760, COSV56178879; called by muse, mutect2, varscan2
- CBFA2T3 | c.1567G>C p.E523Q | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV51923820; called by muse, mutect2, varscan2
- CCDC178 | c.133C>T p.Q45* | Nonsense Mutation (SNP) | VAF 7/38 reads (18%) | catalogued as rs1446667228, COSV100284456, COSV55795877; called by muse, mutect2, varscan2
- CDC25A | c.893G>A p.S298N | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV56769941; called by muse, mutect2
- CDX1 | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140956520, COSV51567579; called by muse, mutect2, varscan2
- CEP85L | c.2294G>A p.S765N | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.797); catalogued as COSV63820949, COSV63824950; called by muse, mutect2
- CHD6 | c.2636C>G p.S879C | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV58554396; called by muse, mutect2, varscan2
- CNGB1 | c.529T>G p.S177A | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as COSV51898208; called by muse, mutect2, varscan2
- COL15A1 | c.2665G>A p.A889T | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.018); catalogued as COSV66641723; called by muse, mutect2, varscan2
- CPNE8 | c.689A>G p.K230R | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.914); catalogued as COSV58838951; called by muse, mutect2, varscan2
- CPT1A | c.2315A>G p.K772R | Missense Mutation (SNP) | VAF 50/82 reads (61%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV55753444; called by muse, mutect2, varscan2
- CSRP3 | c.421C>A p.H141N | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV99788214; called by muse, mutect2
- CTR9 | c.2372G>A p.R791K | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.85); PolyPhen benign (0.01); catalogued as COSV63727969; called by muse, mutect2, varscan2
- CTSF | c.1063G>A p.D355N | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.042); catalogued as rs750756497, COSV59747727; called by muse, mutect2, varscan2
- CUL1 | c.1811C>T p.S604L | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1236894600, COSV57387036; called by muse, mutect2, varscan2
- DCDC1 | c.5101A>C p.K1701Q (on ENST00000597505 / NM_001367979.1; = p.K808Q on NM_020869.3) | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.046); catalogued as COSV57997771; called by muse, mutect2, varscan2
- DHX40 | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs1297977658, COSV52066324; called by muse, mutect2, varscan2
- DMKN | c.473G>A p.G158E | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV60084985; called by muse, mutect2, varscan2
- DNAH7 | c.4566A>T p.E1522D | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.267); catalogued as COSV56754120; called by muse, mutect2, varscan2
- DSC3 | c.1871G>A p.S624N | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs369208762, COSV64571937; called by muse, mutect2, varscan2
- EBAG9 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV61752757; called by muse, varscan2
- ELF1 | c.52G>A p.V18I | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as rs760051911, COSV53497310; called by muse, mutect2, varscan2
- EPB41L1 | c.632C>T p.T211M | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1409685376, COSV52434506; called by muse, mutect2, varscan2
- EPHB2 | c.733G>T p.G245C | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65860222; called by muse, mutect2, varscan2
- EPS8L3 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.874); catalogued as rs202174892, COSV100719698; called by muse, mutect2, varscan2
- ERBB3 | c.3565G>A p.E1189K | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.91); PolyPhen benign (0.299); catalogued as COSV57247809; called by muse, mutect2, varscan2
- FAM193A | c.1714C>G p.P572A | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.121); catalogued as COSV61191402; called by muse, mutect2, varscan2
- FRMD1 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as rs915887041, COSV51960349; called by muse, mutect2, varscan2
- FSIP2 | c.19298C>G p.S6433* | Nonsense Mutation (SNP) | VAF 13/57 reads (23%) | catalogued as COSV100554824; called by muse, mutect2, varscan2
- FUS | c.1051A>G p.I351V | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.656); catalogued as COSV54215746; called by muse, mutect2, varscan2
- FUT8 | c.667C>T p.Q223* (on ENST00000360689 / NM_001371534.1; = p.Q60* on NM_004480.4) | Nonsense Mutation (SNP) | VAF 9/53 reads (17%) | catalogued as COSV100651307; called by muse, mutect2, varscan2
- GPRC6A | c.2501G>T p.C834F | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs367740558; called by muse, mutect2, varscan2
- GTF2IRD2B | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 44/71 reads (62%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.956); catalogued as COSV57030112; called by muse, mutect2, varscan2
- HARBI1 | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.018); catalogued as rs1565358942, COSV56317837; called by muse, mutect2, varscan2
- HCRTR2 | c.555T>G p.I185M | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as COSV63794123; called by muse, mutect2, varscan2
- HNRNPU | c.340G>A p.G114R | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV51689479; called by muse, mutect2, varscan2
- HOXB5 | c.166G>T p.V56F | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.132); catalogued as COSV53312208; called by muse, varscan2
- IMPG1 | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as rs767983922, COSV64054680; called by mutect2, varscan2
- ITPRID1 | c.1843G>T p.E615* | Nonsense Mutation (SNP) | VAF 17/69 reads (25%) | catalogued as rs1277312206, COSV100086185; called by muse, mutect2, varscan2
- KAT14 | c.689C>G p.S230* | Nonsense Mutation (SNP) | VAF 31/75 reads (41%) | catalogued as COSV100890065; called by muse, mutect2, varscan2
- KCNC1 | c.934G>A p.V312I | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.998); catalogued as COSV99789096; called by muse, mutect2
- KCNH4 | c.1213G>A p.G405S | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.192); catalogued as COSV52915780; called by muse, mutect2, varscan2
- KCTD10 | c.520T>A p.Y174N | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57325999; called by muse, mutect2, varscan2
- KIAA1614 | c.358C>T p.R120* | Nonsense Mutation (SNP) | VAF 25/67 reads (37%) | catalogued as rs201123018; called by muse, mutect2, varscan2
- KIF12 | c.947C>T p.P316L (on ENST00000640217; = p.P178L on NM_138424.1) | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65116765; called by muse, mutect2, varscan2
- KIF19 | c.515G>T p.R172L | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as rs773986695, COSV63428890, COSV63428927; called by muse, mutect2, varscan2
- L3MBTL3 | c.1952C>T p.S651L | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs766230271, COSV62384591; called by muse, mutect2, varscan2
- LENG1 | c.256G>C p.G86R | Missense Mutation (SNP) | VAF 68/119 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.527); catalogued as COSV55360670; called by muse, mutect2, varscan2
- LILRB1 | c.2013G>T p.L671F (on ENST00000427581; = p.L620F on NM_006669.6) | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.447); catalogued as rs634222; called by muse, mutect2
- LRIG3 | c.2926C>A p.P976T | Missense Mutation (SNP) | VAF 50/104 reads (48%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.255); catalogued as COSV57861301; called by muse, mutect2, varscan2
- LRRC14B | c.1291C>T p.P431S | Missense Mutation (SNP) | VAF 95/210 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.121); catalogued as COSV57256217; called by muse, mutect2, varscan2
- MAST1 | c.219del p.A74Pfs*103 | Frame Shift Del (DEL) | VAF 36/72 reads (50%) | catalogued as COSV99262622; called by mutect2, pindel, varscan2
- MCHR1 | c.1084T>C p.Y362H | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50760440; called by muse, mutect2, varscan2
- MED4 | c.70A>G p.N24D | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as rs539154677, COSV51638777; called by muse, mutect2, varscan2
- MFN1 | c.1558A>C p.I520L | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.607); catalogued as COSV54938322; called by muse, mutect2, varscan2
- MPHOSPH8 | c.1552G>A p.V518M | Missense Mutation (SNP) | VAF 50/80 reads (63%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs778330655, COSV64054518; called by muse, mutect2, varscan2
- MUC5B | c.13297T>C p.S4433P | Missense Mutation (SNP) | VAF 21/211 reads (10%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV71590001, COSV71590384; called by muse, mutect2
- NOTUM | c.836G>A p.C279Y | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68825818; called by muse, mutect2, varscan2
- NPLOC4 | c.917G>C p.R306P | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV100480713, COSV100480837; called by muse, mutect2
- NT5C1B | c.1589C>A p.P530H (on ENST00000359846 / NM_001199086.2; = p.P470H on NM_033253.4) | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58394623; called by muse, mutect2, varscan2
- NUP214 | c.2753A>G p.N918S | Missense Mutation (SNP) | VAF 42/178 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.019); catalogued as rs368794563; called by muse, mutect2, varscan2
- OR4D5 | c.493C>T p.Q165* | Nonsense Mutation (SNP) | VAF 9/101 reads (9%) | catalogued as COSV100189884; called by muse, mutect2
- PARP10 | c.1387G>C p.E463Q | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV57296914; called by muse, mutect2, varscan2
- PDXDC1 | c.1574A>G p.Y525C | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV55073742; called by muse, mutect2, varscan2
- PKN2 | c.1321C>T p.R441W | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs868792109, COSV100281483; called by muse, mutect2
- POLR1B | c.2845_2846insTGTA p.P949Lfs*17 | Frame Shift Ins (INS) | VAF 13/62 reads (21%) | catalogued as COSV54495253; called by mutect2, pindel, varscan2
- PRAMEF1 | c.437C>A p.P146H | Missense Mutation (SNP) | VAF 55/298 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60006586; called by muse, mutect2, varscan2
- PREX2 | c.1198A>C p.K400Q | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV55754151; called by muse, mutect2
- PRKDC | c.11853G>A p.Q3951= | Splice Region (SNP) | VAF 12/22 reads (55%) | catalogued as COSV100039921; called by muse, mutect2
- PSMB9 | c.622A>G p.I208V | Missense Mutation (SNP) | VAF 36/288 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.009); catalogued as COSV66399333; called by muse, mutect2, varscan2
- RBBP8NL | c.613C>T p.R205* | Nonsense Mutation (SNP) | VAF 12/41 reads (29%) | catalogued as rs1292531905, COSV99436503; called by muse, mutect2, varscan2
- RGS12 | c.886G>T p.A296S | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60902517; called by muse, mutect2
- RIPOR1 | c.1349G>A p.R450Q (on ENST00000379312 / NM_001193522.2; = p.R446Q on NM_024519.4) | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs773792869, COSV50217719; called by muse, mutect2, varscan2
- RNF43 | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs764759712, COSV60415484, COSV60418935; called by muse, mutect2, varscan2
- RPL23A | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.537); catalogued as rs759848914, COSV52643766; called by muse, mutect2, varscan2
- S1PR1 | c.790G>A p.V264I | Missense Mutation (SNP) | VAF 9/155 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as COSV59512501; called by muse, mutect2
- SDC2 | c.481A>G p.I161V | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.855); catalogued as COSV56226141; called by muse, mutect2, varscan2
- SDE2 | c.525G>T p.M175I | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs1319027054, COSV55250115; called by muse, mutect2, varscan2
- SERPINA5 | c.23G>A p.C8Y | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.819); catalogued as COSV61573652, COSV61574121; called by mutect2, varscan2
- SHC1 | c.1060C>G p.P354A (on ENST00000368445 / NM_183001.5; = p.P244A on NM_003029.5) | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV63534587; called by muse, mutect2, varscan2
- SPG11 | c.2081G>A p.S694N | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV55991570; called by muse, mutect2, varscan2
- TBX15 | c.1807T>A p.*603Kext*82 (on ENST00000369429 / NM_001330677.2; = p.*497Kext*82 on NM_152380.3) | Nonstop Mutation (SNP) | VAF 37/82 reads (45%) | catalogued as COSV99253949; called by muse, mutect2, varscan2
- TENM3 | c.4690C>A p.L1564I | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.264); catalogued as COSV69300294; called by muse, mutect2, varscan2
- TM9SF4 | c.1124G>A p.R375Q | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV54104871; called by muse, mutect2, varscan2
- TMC4 | c.437C>T p.A146V (on ENST00000617472 / NM_001145303.3; = p.A140V on NM_144686.4) | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs1193886083, COSV55474563; called by muse, mutect2, varscan2
- TMPRSS15 | c.2365A>G p.S789G | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs777652405, COSV53035615; called by muse, mutect2, varscan2
- TPH2 | c.426G>T p.W142C | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV61590776; called by muse, mutect2, varscan2
- TSGA10 | c.1607T>C p.I536T | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.55); catalogued as rs1335078696, COSV100747500; called by muse, mutect2
- TTN | c.18548T>C p.M6183T (on ENST00000591111; = p.M5256T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/44 reads (59%) | PolyPhen benign (0.116); catalogued as rs1309078933, COSV59913045; called by muse, mutect2, varscan2
- UPF3A | c.907G>C p.E303Q | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV100677576; called by muse, mutect2, varscan2
- USP14 | c.248C>T p.S83L | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV55279215; called by muse, mutect2, varscan2
- USP2 | c.1256T>G p.L419R | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52727516; called by mutect2, varscan2
- WAC | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.031); catalogued as COSV61566896; called by muse, mutect2, varscan2
- ZC3H4 | c.1287C>G p.I429M | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV53410859, COSV53414600; called by muse, mutect2, varscan2
- ZFAT | c.545A>G p.Q182R | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.26); catalogued as COSV64735269; called by muse, mutect2, varscan2
- ZNF16 | c.749C>A p.S250* | Nonsense Mutation (SNP) | VAF 75/183 reads (41%) | catalogued as COSV99429577; called by muse, mutect2, varscan2
- ZNF277 | c.620T>A p.I207N | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV62463368; called by muse, mutect2, varscan2
- ZNF567 | c.665G>A p.R222K (on ENST00000536254 / NM_001322913.1; = p.R191K on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/38 reads (71%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62444416; called by muse, mutect2, varscan2
- ANKRD12 | c.4053_4055delinsTT p.S1352* | Frame Shift Del (DEL) | VAF 13/94 reads (14%) | called by pindel, varscan2*
- ARID1A | c.1522_1529del p.P508Afs*112 | Frame Shift Del (DEL) | VAF 26/151 reads (17%) | called by mutect2, pindel, varscan2
- GTF2IRD2B | c.2590G>C p.E864Q | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- NCOR1 | c.2444_2446delinsTT p.P815Lfs*12 | Frame Shift Del (DEL) | VAF 32/41 reads (78%) | called by pindel, varscan2*
- RB1 | c.576_581delinsG p.V193Lfs*8 | Frame Shift Del (DEL) | VAF 24/45 reads (53%) | called by pindel, varscan2*
- VRK2 | c.98del p.K33Rfs*10 | Frame Shift Del (DEL) | VAF 21/44 reads (48%) | called by mutect2, pindel, varscan2
- ADRA2B | c.1113C>T p.F371= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as rs976762879, COSV69787247; called by muse, varscan2
- ANKRD12 | c.1407A>G p.K469= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as rs990121510, COSV50819862; called by muse, mutect2, varscan2
- ANKRD12 | c.3597C>G p.L1199= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV50819874; called by muse, mutect2, varscan2
- ARHGAP39 | c.2070G>A p.S690= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as rs371616316; called by muse, mutect2, varscan2
- BMS1 | c.3768G>A p.K1256= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as COSV65733160; called by muse, mutect2, varscan2
- C20orf194 | c.3474G>A p.E1158= | Silent (SNP) | VAF 13/148 reads (9%) | catalogued as COSV52692277; called by muse, mutect2
- CABP4 | c.384C>T p.P128= | Silent (SNP) | VAF 39/81 reads (48%) | catalogued as rs376274257; called by muse, mutect2, varscan2
- CACNA1D | c.4725T>C p.A1575= (on ENST00000350061 / NM_001128840.3; = p.A1595= on NM_000720.4) | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV55439368; called by muse, mutect2, varscan2
- CADPS | c.3216C>T p.D1072= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs1560955758, COSV51869381; called by muse, mutect2, varscan2
- CAPG | c.528C>G p.A176= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as COSV55708832, COSV99809367; called by muse, mutect2
- CEP97 | c.261G>A p.L87= | Silent (SNP) | VAF 117/214 reads (55%) | catalogued as COSV59122831; called by muse, mutect2, varscan2
- COL12A1 | c.5550G>C p.L1850= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV100485789; called by muse, mutect2
- DCDC1 | c.5328G>T p.L1776= (on ENST00000597505 / NM_001367979.1; = p.L883= on NM_020869.3) | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV57997764; called by muse, mutect2, varscan2
- DNAH8 | c.9531A>G p.A3177= | Silent (SNP) | VAF 38/71 reads (54%) | catalogued as COSV59429234; called by muse, mutect2, varscan2
- ECH1 | c.216C>G p.L72= | Silent (SNP) | VAF 24/119 reads (20%) | catalogued as COSV55488722; called by muse, mutect2, varscan2
- EME2 | c.936C>G p.V312= | Silent (SNP) | VAF 4/8 reads (50%) | catalogued as COSV99456905; called by muse, mutect2, varscan2
- EPHA3 | c.2632C>T p.L878= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as COSV60695953, COSV60723474; called by muse, mutect2, varscan2
- FAM111B | c.1788C>T p.N596= | Silent (SNP) | VAF 39/87 reads (45%) | catalogued as rs767378484, COSV59111237; called by muse, mutect2, varscan2
- G6PC2 | c.624G>A p.L208= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as rs1418821680, COSV56371631; called by muse, mutect2, varscan2
- GRK2 | c.1788C>T p.A596= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV57751005; called by muse, mutect2, varscan2
- GRM3 | c.801C>T p.P267= | Silent (SNP) | VAF 26/34 reads (76%) | catalogued as COSV64468002; called by muse, mutect2, varscan2
- GRXCR1 | c.60C>T p.I20= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as rs267600162, COSV67669835; called by muse, mutect2, varscan2
- GTPBP2 | c.861C>T p.V287= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV61075757; called by muse, mutect2, varscan2
- H3C3 | c.405G>A p.R135= | Silent (SNP) | VAF 45/70 reads (64%) | catalogued as rs150572643; called by muse, mutect2, varscan2
- HECTD4 | c.2748A>G p.L916= | Silent (SNP) | VAF 25/101 reads (25%) | catalogued as COSV61177993; called by muse, mutect2, varscan2
- HGS | c.474A>G p.P158= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as rs757934791, COSV61266807; called by muse, mutect2, varscan2
- ITGA7 | c.2715C>G p.L905= (on ENST00000555728; = p.L861= on NM_002206.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as COSV57692516; called by muse, mutect2, varscan2
- IZUMO1 | c.996A>G p.G332= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as rs1172128591, COSV55803020; called by mutect2, varscan2
- JCAD | c.1617A>G p.R539= | Silent (SNP) | VAF 52/112 reads (46%) | catalogued as rs1243115272, COSV100948559, COSV64758242; called by muse, mutect2, varscan2
- KRTAP19-7 | c.9C>T p.Y3= | Silent (SNP) | VAF 33/55 reads (60%) | catalogued as rs761458515, COSV58365958; called by muse, mutect2, varscan2
- LAMB4 | c.3321G>C p.G1107= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as COSV52714513, COSV52718203; called by muse, mutect2, varscan2
- LFNG | c.834C>T p.F278= (on ENST00000222725 / NM_001040167.2; = p.F149= on NM_002304.2) | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as rs772525075, COSV56068771; called by muse, mutect2, varscan2
- LMNB1 | c.1149C>T p.G383= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as rs1450813982, COSV54396776; called by muse, mutect2, varscan2
- MAPKBP1 | c.33G>A p.R11= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as COSV52958579; called by muse, mutect2, varscan2
- MLXIPL | c.828C>T p.V276= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as rs368793037; called by muse, mutect2, varscan2
- MPPED1 | c.63C>T p.C21= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as rs780341898, COSV100501203; called by muse, varscan2
- MSH6 | c.957G>A p.T319= | Silent (SNP) | VAF 16/162 reads (10%) | catalogued as rs375210430; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- MYLK | c.4566C>T p.V1522= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as COSV60605594; called by muse, mutect2, varscan2
- MYO10 | c.5187G>A p.L1729= | Silent (SNP) | VAF 3/33 reads (9%) | catalogued as COSV99945161; called by muse, mutect2
- NAIF1 | c.573G>A p.E191= | Silent (SNP) | VAF 27/80 reads (34%) | catalogued as COSV66089959; called by muse, mutect2, varscan2
- NALCN | c.216C>T p.F72= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as COSV51915386; called by muse, mutect2, varscan2
- NDC1 | c.1830T>C p.H610= | Silent (SNP) | VAF 23/76 reads (30%) | catalogued as COSV52333657; called by muse, mutect2, varscan2
- OR11H12 | c.150T>C p.Y50= | Silent (SNP) | VAF 23/135 reads (17%) | catalogued as COSV73543492; called by muse, mutect2, varscan2
- PCDHAC1 | c.249C>T p.R83= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV53838945; called by muse, mutect2, varscan2
- PKD1 | c.9702G>T p.V3234= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV99237850; called by muse, mutect2, varscan2
- PLXNB1 | c.864G>T p.A288= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as rs758795276, COSV56487157; called by muse, mutect2, varscan2
- PPP1R13B | c.2388A>G p.L796= | Silent (SNP) | VAF 46/53 reads (87%) | catalogued as COSV52449216; called by muse, varscan2
- PRAMEF1 | c.438C>A p.P146= | Silent (SNP) | VAF 56/300 reads (19%) | catalogued as COSV100179552, COSV60006598; called by muse, mutect2, varscan2
- RNF170 | c.573C>T p.V191= | Silent (SNP) | VAF 30/89 reads (34%) | catalogued as rs369696416; called by muse, mutect2, varscan2
- RUSC1 | c.105G>A p.G35= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as rs1267841231, COSV52738355; called by muse, mutect2, varscan2
- SLCO5A1 | c.1563A>G p.L521= | Silent (SNP) | VAF 24/130 reads (18%) | catalogued as rs1234734885, COSV52654831; called by muse, mutect2, varscan2
- SLITRK5 | c.783T>C p.D261= | Silent (SNP) | VAF 24/104 reads (23%) | catalogued as COSV61521313; called by muse, mutect2, varscan2
- SMU1 | c.349C>T p.L117= | Silent (SNP) | VAF 14/113 reads (12%) | catalogued as COSV68139633; called by muse, mutect2, varscan2
- SNRPA | c.66G>A p.K22= | Silent (SNP) | VAF 61/88 reads (69%) | catalogued as COSV54680520; called by muse, mutect2, varscan2
- SORL1 | c.384G>A p.A128= | Silent (SNP) | VAF 28/105 reads (27%) | catalogued as rs772201413, COSV52749705; called by muse, mutect2, varscan2
- SPSB2 | c.69C>G p.L23= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV51290029; called by muse, varscan2
- SULF1 | c.1260T>G p.R420= | Silent (SNP) | VAF 26/97 reads (27%) | catalogued as COSV52674458; called by muse, mutect2, varscan2
- TACC3 | c.1278C>T p.C426= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as rs1416557954, COSV57603151; called by muse, mutect2, varscan2
- TARBP1 | c.1668C>T p.L556= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as rs1197277635, COSV50178910; called by muse, mutect2, varscan2
- TET3 | c.882C>A p.V294= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as rs772948741, COSV59880289; called by muse, mutect2, varscan2
- THSD7B | c.3012C>T p.S1004= | Silent (SNP) | VAF 21/47 reads (45%) | catalogued as rs549789351, COSV55660062; called by muse, mutect2, varscan2
- TMEM143 | c.234C>T p.S78= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV53155379, COSV99507669; called by muse, mutect2, varscan2
- TMEM161A | c.1176C>G p.L392= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs1426188976, COSV50776230; called by muse, mutect2, varscan2
- UMODL1 | c.900G>A p.T300= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as rs772466771, COSV68555057, COSV68556815; called by muse, mutect2, varscan2
- ZNF366 | c.762G>A p.Q254= | Silent (SNP) | VAF 20/79 reads (25%) | catalogued as COSV59214094; called by muse, mutect2, varscan2
- ZNF93 | c.159C>T p.I53= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as rs775871832, COSV59374285; called by muse, mutect2, varscan2
- AFDN | chr6:167825994 G>T | 5'Flank (SNP) | VAF 9/138 reads (7%) | called by muse, mutect2
- AP000769.5 | chr11:65500883 G>A | 5'Flank (SNP) | VAF 16/30 reads (53%) | called by muse, mutect2, varscan2
- DPP6 | c.*312C>T | 3'UTR (SNP) | VAF 31/40 reads (78%) | catalogued as COSV100124649; called by muse, mutect2, varscan2
- MIR1283-2 | n.28C>A | RNA (SNP) | VAF 24/152 reads (16%) | called by muse, mutect2, varscan2
